Surgical pathology report (de-identified scan), TCGA case TCGA-55-A57B, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-A57B-01A (Primary Tumor).

[page 1 of 6]
Patient:

Referring Physician:

Gender: F

Ref#:

Hosp#:

Patient Location:

Date of Service:

Date Received:

Inpatient

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

- A. - I.) LUNG, LEFT, UPPER LOBE, HILAR (N10L X4), PERI-AORTIC (N6), SUBCARINAL (N7), PULMONARY LIGAMENT (N9L) AND PERIBRONCHIAL (N11L) LYMPH NODES, LOBECTOMY WITH REGIONAL LYMPH NODE DISSECTION:
- INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA.
- 3 cm in maximum dimension.
- Visceral pleura invasion: NOT IDENTIFIED.
- Arising in association with a scar.
- MARGIN STATUS: NEGATIVE.
- FIFTEEN LYMPH NODES, NEGATIVE FOR METASTASIS (0/15).
- SEE PATHOLOGIC TUMOR STAGING SUMMARY BELOW.

PATHOLOGIC TUMOR STAGING SUMMARY:

Type and grade: Adenocarcinoma, poorly differentiated.

Primary tumor: pT1b (3 cm in maximum dimension, without visceral pleura invasion).

Regional lymph nodes: pN0 (fifteen lymph nodes, negative for metastasis).

Distant metastasis: Not applicable.

Pathologic stage: IA.

Lymphovascular invasion: Not identified.

Margin status: R0.

ICD-O-3
Adenocarcinoma w/ mixed subtypes (solid & acinar)
Site: Lung, upper lobe
Q34.1
8455/3

Lung Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol.

[page 2 of 6]
Patient:

Case #:

Specimen:	Lung, upper lobe with N10, N6, N7, N9, and N11 lymph nodes.
Procedure:	Lobectomy with regional lymph node dissection.
Specimen integrity:	Intact.
Specimen laterality:	Left.
TUMOR FEATURES:	
Tumor site:	Left lung upper lobe.
Tumor size:	Greatest dimension: 3 cm.
Additional dimensions:	2.3 x 1.8 cm.
Tumor focality:	Unifocal.
Histologic type:	Adenocarcinoma, with acinar and solid patterns.
Histologic grade:	Poorly differentiated (grade 3).
Visceral pleural invasion:	Not identified.
Tumor extension:	Confined to the lung.
MARGIN:	
Bronchial margin:	Negative (R0).
Vascular margin:	Uninvolved by invasive carcinoma.
Parenchymal margin:	Uninvolved by invasive carcinoma.
Parietal pleural margin:	Uninvolved by invasive carcinoma.
Chest wall margin:	Not applicable.
Treatment effect:	Not applicable.
Lymphovascular invasion:	Not identified.
LYMPH NODES:	 Fifteen lymph nodes, negative for metastasis (0/15).
PATHOLOGIC STAGING:	
Primary tumor:	pT1b (3 cm in greatest dimension).
Regional lymph nodes:	pN0 (0/15).
Distant metastasis:	Not applicable.
Pathologic stage:	IA.
Additional pathologic findings:	 Emphysematous changes, with subpleural blebs and subpleural fibrosis.

Case #:

[page 3 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Lymph node;N10L
- B. Lymph node;N10L #2
- C. Lung;Left Upper Lobe
- D. Lymph node;N10L #3
- E. Lymph node;N6
- F. Lymph node;N7
- G. Lymph node;N10L #4
- H. Lymph node;N9L
- I. Lymph node;N11L

Clinical History/Operative Dx:

Adenocarcinoma left lung.

Intraoperative Diagnosis:

- C. Left upper lobe: Tumor present in peribronchial lung tissue; bronchial margin negative [REDACTED]
[REDACTED]. The intraoperative interpretation(s) was/were performed and rendered at [REDACTED]

Gross Description:

- A. The specimen is labeled N10L and is received in formalin. It consists of a 0.3 cm fragment of dark anthracotic tissue which is submitted intact in cassette A1. [REDACTED]
- B. The specimen is labeled N10L #2 and is received in formalin. It consists of a 0.5 x 0.4 x 0.3 cm fragment of red-yellow to gray-brown, focally cauterized tissue. It is submitted intact in cassette B1. [REDACTED]
- C. The specimen is labeled left upper lobe and is received without fixative. It consists of an 18.8 x 9.5 x 3 cm lobe of lung which weighs 101 grams. The pleural surface is predominantly pink-tan to pale red but in the central medial portion of the lung, there is retraction and irregularity of the pleural surface with an adjacent 4 cm area of violaceous discoloration of the pulmonary parenchyma. The retracted pleural surface is inked green. There is a single bleb at the medial apical surface of the lung. At the hilum staple lines are present, both superiorly, inferiorly, and across the bulbar bronchus. The lobar bronchus is removed as a thin shave and is submitted for frozen section as CFS. There are scattered small and slightly larger peribronchial nodes which are up to 0.6 cm maximally. Serial sections of the retracted central medial pleural surface reveal an underlying pale yellow, firm neoplasm which measures 3 x 2.3 x 1.8 cm. It abuts the pleural surface of the medial lung and is 0.4 cm from the closest bronchial resection margin. It is 2 cm from the closest interlobar staple line at the inferior hilum. It appears to grossly erode into an adjacent segmental bronchus. Sections of the remainder of the lung reveal slight consolidation adjacent to the tumor but otherwise well-aerated pulmonary parenchyma. Representative sections are submitted.

Case #:

Page 3

This report continues... (FINAL)

[page 4 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Representative tumor and uninvolved lung are retained for research purposes.

Section summary: C1) bronchial margin from frozen section, C2) vascular margins, C3) peribronchial nodes, C4-C6) sections of tumor and pleural surface, C7) sections of tumor and adjacent segmental bronchus, C8) apical lung with bleb, C9) uninvolved apical mid and basilar lung.

D. The specimen is labeled N10L #3 and is received in formalin. It consists of a 1.1 x 0.7 x 0.6 cm fragment of mottled, gray-tan to red-brown tissue which is focally calcified. It is serially sectioned and submitted in cassette D1 for decalcification.

E. The specimen is labeled N6 and is received in formalin. It consists of three 0.4-0.8 cm strips of dark red tissue which are submitted intact in cassette E1.

F. The specimen is labeled N7 and is received in formalin. It consists of a 0.8 x 0.3 x 0.1 cm strip of pale red to anthracotic tissue which is submitted intact in cassette F1.

G. The specimen is labeled N10L #4 and is received in formalin. It consists of a 0.7 x 0.5 x 0.2 cm fragment of pink-tan to anthracotic tissue which is submitted intact in cassette G1.

H. The specimen is labeled N9L and is received in formalin. It consists of a 0.2 cm fragment of anthracotic tissue which is submitted intact in cassette H1.

I. The specimen is labeled N11L and is received in formalin. It consists of two strips of dull red to anthracotic tissue which vary from 0.8-1 cm in length and are up to 0.3 cm in diameter. The specimen is submitted intact in cassette I1.

Microscopic Description:

A. Sections demonstrate one lymph node, negative for metastasis.

B. Sections demonstrate one lymph node, negative for metastasis.

C. Sections demonstrate lung tissue, containing infiltrating neoplasm, composed predominantly of angulated glands, lined by cuboidal epithelial cells, with large hyperchromatic nuclei, markedly pleomorphism and prominent nucleoli. In other areas of the tumor, the neoplastic cells are in solid nests or single cells. Ten peribronchial lymph nodes, negative for tumor are identified. Elastic stain, performed on block C4, with adequate control, confirms the absence of visceral pleural invasion.

D. Sections demonstrate lymphoid tissue, containing a central hyalinized and calcified nodule. Metastatic carcinoma is not identified.

E. Sections demonstrate fibrovascular tissue and adipose tissue and blood. No lymphoid tissue is identified.

[page 5 of 6]
Case #:

FINAL SURGICAL PATHOLOGY REPORT

- F. Sections demonstrate one lymph node, negative for metastasis.
- G. Sections demonstrate one lymph node, negative for metastasis.
- H. Sections demonstrate one lymph node, negative for metastasis.
- I. Sections demonstrate one lymph node, negative for metastasis.

Note:

Pathologic diagnostic form confirms
diagnostic path report which indicated
solid and acinar types. 2/18/13 Page 5

Case #:

END OF REPORT (FINAL)		
IHP/AA Discrepancy		X

10/19/12

[page 6 of 6]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Unique Patient Identifier: _____ UC # _____

Completed By (Interviewer Name on OpenClinica) _____ Completed Date: _____

Diagnosis Information			
	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Adenocarcinoma, with acinar and solid patterns	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Lung Acinar Adenocarcinoma *	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Only one slide is reviewed. The features appear consistent with a poorly differentiated adenocarcinoma, mixed type, with approximately 50% solid + 50% acinar components.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairperson has been informed or is aware of the above discrepancy in diagnoses.

Investigator Signature

Date

* Per discussion w/ _____ the diagnosis on the revised CQCF in OpenClinica was changed to reflect "Mixed Adenocarcinoma" per the Discrepancy Note in #3 above.

Source: NCI Genomic Data Commons file 9614baf3-8f74-45e2-b1b3-235522fb4899 (TCGA-55-A57B.8231F2AB-F7AC-4866-BFA0-F902E2EC18B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).